Somatic mutation profile of tumor specimen TCGA-ZB-A965-01A (aliquot TCGA-ZB-A965-01A-11D-A428-09) from TCGA case TCGA-ZB-A965, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type A, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 75.6 years (27,617 days).
Specimen TCGA-ZB-A965-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3962c70e-6346-489a-9035-59a183c70a87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A965-10A (Blood Derived Normal), aliquot TCGA-ZB-A965-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa115577-90e1-4ee5-a463-b55a7b19b890

The open-access MAF lists 24 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 17, Silent 3, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 142/387 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 14/23 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM30 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs984058539; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV56263190; called by pindel, varscan2
- CD3E | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62345486; called by muse, mutect2, varscan2
- CTNNB1 | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV62700183; called by muse, mutect2, varscan2
- LRRC7 | c.1583G>A p.R528H (on ENST00000651989 / NM_001370785.2; = p.R495H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as rs750231315, COSV50488265; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- NFATC4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51608664; called by muse, varscan2
- NR0B1 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs754504237; called by muse, mutect2, varscan2
- PHOX2B | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as rs779068107; ClinVar: uncertain significance; called by muse, mutect2
- SCN4A | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as rs1323000570; called by muse, mutect2, varscan2
- SYNE1 | c.6094G>C p.E2032Q (on ENST00000367255 / NM_182961.4; = p.E2039Q on NM_033071.3) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs367594476; called by muse, mutect2, varscan2
- AMER1 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- GET4 | c.959_961del p.D320del | In Frame Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- LZTR1 | c.259A>G p.N87D | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- METTL14 | c.940A>G p.I314V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MUC16 | c.23699C>G p.S7900* | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.736_742del p.P246Vfs*50 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- SORL1 | c.6424C>T p.P2142S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- TCF20 | c.3171A>C p.E1057D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRPF1 | c.2712G>T p.P904= | Silent (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- CDH22 | c.351C>T p.G117= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs770894396, COSV64838628; called by muse, mutect2, varscan2
- PLIN2 | c.543C>A p.T181= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1378213580; called by muse, mutect2, varscan2
